TCGA case TCGA-XX-A89A — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Spectrum Health. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ca20249f-b7ea-4fd9-9ecb-34f74755ae35

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 68 years; Vital status: Alive.

Diagnoses (1)
1. Lobular carcinoma, NOS: ICD-O-3 morphology code: 8520/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 68.4 years (25,000 days); Year of diagnosis: 2013; Method of diagnosis: Core Biopsy; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, Left Upper Outer.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 11.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 59 days; Days to treatment end: 112 days; Treatment dose: 1,800 cGy; Treatment outcome: Complete Response; Number of fractions: 10; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 59 days; Days to treatment end: 112 days; Treatment dose: 3,240 cGy; Treatment outcome: Complete Response; Number of fractions: 18; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 278 days; Disease response: Tumor Free.
- Days to follow up: 488 days (1.3 years); Disease response: Tumor Free.

Molecular and laboratory tests
- ERBB2 (IHC): Negative.
- ESR1 (IHC): Positive; Test value range: 70-79%.
- PGR (IHC): Positive; Test value range: 70-79%.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Postmenopausal.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-XX-A89A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 250 mg.
  Slide TCGA-XX-A89A-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-XX-A89A-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-XX-A89A-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: Tumor free; Lymph nodes examined: Yes; Surgical procedure first: Simple Mastectomy; Histologic diagnosis: Infiltrating Lobular Carcinoma; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); Method initial path diagnosis: Core needle biopsy; Pr positivity scale other: moderately to strongly; Er positivity scale other: moderately to strongly; Prospective collection: No; Retrospective collection: Yes; New tumor event diagnosis indicator: No.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Left Upper Outer Quadrant.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 488 days; disease-specific survival: no event (censored), 488 days; disease-free interval: no event (censored), 488 days; progression-free interval: no event (censored), 488 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-XX-A89A-01A-11D-A36I-01): tumor purity 0.34, ploidy 3.46, whole-genome doublings 1.
